TCGA case TCGA-WB-A80P — Pheochromocytoma and Paraganglioma (TCGA-PCPG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Paragangliomas and Glomus Tumors; Primary site: Retroperitoneum and peritoneum; Tissue source site: Erasmus MC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3b6b1088-662a-4a66-8134-97d385eb5ae9

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Netherlands; Age at index: 20 years; Vital status: Alive.

Diagnoses (6)
1. Extra-adrenal paraganglioma, malignant (the primary disease): ICD-O-3 morphology code: 8693/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 20.8 years (7,608 days); Year of diagnosis: 1988; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 9,634 days (26.4 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes tested: 1.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.
2. Metastasis of diagnosis 1 (Extra-adrenal paraganglioma, malignant), site: Lymph node, NOS. Age at diagnosis: 39.6 years (14,474 days); Days to diagnosis: 6,866 days (18.8 years); Prior treatment: Yes.
3. Metastasis of diagnosis 1 (Extra-adrenal paraganglioma, malignant), site: Bone, NOS. Age at diagnosis: 39.6 years (14,474 days); Days to diagnosis: 6,866 days (18.8 years); Prior treatment: Yes.
4. Metastasis of diagnosis 1 (Extra-adrenal paraganglioma, malignant), site: Lung, NOS. Age at diagnosis: 39.6 years (14,474 days); Days to diagnosis: 6,866 days (18.8 years); Prior treatment: Yes.
5. Metastasis of diagnosis 1 (Extra-adrenal paraganglioma, malignant), site: Lung, NOS. Age at diagnosis: 39.8 years (14,533 days); Days to diagnosis: 6,925 days (19.0 years); Prior treatment: Yes.
6. Metastasis of diagnosis 1 (Extra-adrenal paraganglioma, malignant), site: Bone, NOS. Age at diagnosis: 39.8 years (14,533 days); Days to diagnosis: 6,925 days (19.0 years); Prior treatment: Yes.

Follow-up (8 entries)
- Day 0 (prior to diagnosis): History of tumor: No; History of tumor type: Phenochromocytoma or Paraganglioma.
- Day 6,866 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 6,866 days (18.8 years); Evidence of progression type: Convincing Image Source.
- Day 6,866 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 6,866 days (18.8 years); Evidence of progression type: Convincing Image Source.
- Day 6,866 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 6,866 days (18.8 years); Evidence of progression type: Convincing Image Source.
- Day 6,925 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 6,925 days (19.0 years); Evidence of progression type: Convincing Image Source.
- Day 6,925 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 6,925 days (19.0 years); Evidence of progression type: Convincing Image Source.
- Days to follow up: 9,219 days (25.2 years); Disease response: With Tumor.
- Days to follow up: 9,634 days (26.4 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-WB-A80P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 60 mg.
  Slide TCGA-WB-A80P-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-WB-A80P-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-WB-A80P-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History pheo or para include benign: No; History neoadjuvant treatment: No; Tumor status: With tumor; Treatment outcome first course: Progressive Disease.
- Primary pathology: Submitted tumor site: Extra-adrenal Site; Site of primary tumor other: extra adrenal between aorta and vena cava; Histologic diagnosis: Paraganglioma, Extra-adrenal Pheochromocytoma; Lymph nodes examined: Yes.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 9,634 days; disease-specific survival: no event (censored), 9,634 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 6,866 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-WB-A80P-01A-11D-A35H-01): tumor purity 0.77, ploidy 1.95, whole-genome doublings 0.
